Somatic mutation profile of tumor specimen 0DJIM3 from CCDI case PBBXAZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,463 days).
Specimen 0DJIM3: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8916cba-095a-4d1f-af9d-a150e1d0705d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJIKV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4899de82-4ce4-4539-9dd9-88143f227b2f

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 2, Intron 2, 5'Flank 2, 5'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 195/641 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218643327, COSV60787034; called by muse, mutect2, varscan2
- TCF12 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 29/559 reads (5%) | catalogued as rs758543580, COSV51016362; ClinVar: pathogenic; called by muse, mutect2
- CTSV | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 213/602 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751076789; called by muse, mutect2, varscan2
- LY75 | c.4491G>A p.W1497* | Nonsense Mutation (SNP) | VAF 30/763 reads (4%) | catalogued as COSV55108556; called by muse, mutect2
- MUC5AC | c.16032C>T p.C5344= | Splice Region (SNP) | VAF 182/756 reads (24%) | catalogued as rs1011969933; called by muse, mutect2, varscan2
- MYH14 | c.5483G>A p.R1828H | Missense Mutation (SNP) | VAF 154/525 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs773798800; called by muse, mutect2, varscan2
- RABGEF1 | c.227G>T p.R76L (on ENST00000439720 / NM_001287061.2; = p.R63L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV99535053; called by muse, mutect2
- SALL1 | c.3665C>T p.A1222V | Missense Mutation (SNP) | VAF 36/642 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.51); catalogued as rs578198178, COSV51755458; called by muse, mutect2
- SLC38A1 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 139/474 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.717); catalogued as rs779568275, COSV67063386, COSV67064340; called by muse, mutect2, varscan2
- ADARB2 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2
- GJA9 | c.696C>G p.H232Q | Missense Mutation (SNP) | VAF 134/460 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- ITGAE | c.1039A>G p.S347G | Missense Mutation (SNP) | VAF 118/434 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYT1 | c.2989G>A p.V997M | Missense Mutation (SNP) | VAF 91/344 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PYGM | c.1743C>G p.C581W | Missense Mutation (SNP) | VAF 330/727 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SNTB2 | c.483C>A p.D161E | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- VANGL2 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 189/645 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADCK5 | c.1305C>T p.P435= | Silent (SNP) | VAF 35/568 reads (6%) | catalogued as rs1032534999; called by muse, mutect2
- BTAF1 | c.936T>C p.I312= | Silent (SNP) | VAF 120/450 reads (27%) | called by muse, mutect2, varscan2
- CCSER2 | c.1197G>A p.L399= | Silent (SNP) | VAF 22/698 reads (3%) | catalogued as COSV56508994; called by muse, mutect2
- HJURP | c.618G>A p.A206= | Silent (SNP) | VAF 192/542 reads (35%) | catalogued as rs1480087141; called by muse, mutect2, varscan2
- MUC22 | c.1965C>A p.T655= | Silent (SNP) | VAF 32/638 reads (5%) | catalogued as rs1236098330; called by muse, mutect2
- AL132655.6 | chr20:58840357 C>T | 5'Flank (SNP) | VAF 177/625 reads (28%) | called by muse, mutect2, varscan2
- BTN1A1P1 | chr6:26476187 C>T | 5'Flank (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- CRADD | c.298+59329C>T | Intron (SNP) | VAF 19/360 reads (5%) | called by muse, mutect2
- MTDHP2 | n.569G>A | RNA (SNP) | VAF 20/492 reads (4%) | called by muse, mutect2
- RPL26L1 | c.-9-52C>T | Intron (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- SOX4 | c.-443T>A | 5'UTR (SNP) | VAF 92/312 reads (29%) | called by mutect2, varscan2
